Somatic mutation profile of tumor specimen HCM-BROD-1186-C64-01A (aliquot HCM-BROD-1186-C64-01A-11D-A881-36) from HCMI case HCM-BROD-1186-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 50.0 years (18,276 days).
Specimen HCM-BROD-1186-C64-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7149f8bd-07d5-429e-aa28-a87313c4ecb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-1186-C64-11A (Solid Tissue Normal), aliquot HCM-BROD-1186-C64-11A-11D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ff836ee-2642-4b69-8d88-59b1937cb538

The open-access MAF lists 86 somatic variants for this specimen: 64 protein-altering or splice-affecting, 17 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 17, Nonsense Mutation 6, Intron 5, Frame Shift Del 4, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3141T>A p.H1047Q | Missense Mutation (SNP) | VAF 24/586 reads (4%) | hotspot (GDC flag); SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV55875891, COSV55920782; called by muse, mutect2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 220/463 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC004593.2 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 187/458 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV56102873; called by muse, mutect2, varscan2
- ATAT1 | c.97A>G p.T33A | Missense Mutation (SNP) | VAF 31/948 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.13); catalogued as rs1176870823; called by muse, mutect2
- C10orf71 | c.1399C>T p.R467* | Nonsense Mutation (SNP) | VAF 130/498 reads (26%) | catalogued as rs773106985; called by muse, mutect2, varscan2
- DEFB112 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 32/631 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV59182453; called by muse, mutect2
- DLGAP2 | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 19/745 reads (3%) | SIFT tolerated (0.86); PolyPhen benign (0.042); catalogued as rs367568530; called by muse, mutect2
- HARS1 | c.1278G>C p.K426N | Missense Mutation (SNP) | VAF 173/537 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV56906176; called by muse, mutect2, varscan2
- HCRTR2 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 66/631 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs201301558, COSV63793801, COSV63798056, COSV63799846; called by muse, mutect2, varscan2
- IRX2 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 81/836 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs763927679, COSV57412900, COSV57412974; called by muse, mutect2
- MYH14 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 54/500 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs750639438; called by muse, mutect2, varscan2
- MYO1G | c.1217G>C p.S406T | Missense Mutation (SNP) | VAF 129/424 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV51854538; called by muse, mutect2, varscan2
- N4BP2L2 | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 171/448 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV57230597; called by muse, mutect2, varscan2
- NAV3 | c.1872C>A p.H624Q | Missense Mutation (SNP) | VAF 48/381 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as COSV57083456; called by muse, mutect2, varscan2
- NDFIP2 | c.654C>G p.D218E | Missense Mutation (SNP) | VAF 147/417 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV54527542; called by muse, mutect2, varscan2
- PBRM1 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 220/397 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56304081, COSV56308416; called by muse, mutect2, varscan2
- PROB1 | c.1592T>C p.I531T | Missense Mutation (SNP) | VAF 306/744 reads (41%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs535719316; called by muse, mutect2, varscan2
- PTPRN2 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 194/511 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as rs748139505, COSV67028084; called by muse, mutect2, varscan2
- SEZ6L | c.2601G>A p.S867= | Splice Region (SNP) | VAF 90/246 reads (37%) | catalogued as rs747361013, COSV50660737; called by muse, mutect2, varscan2
- SLC22A31 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 206/551 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1282082023, COSV57024045; called by muse, mutect2, varscan2
- TUSC3 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as rs1174131081; called by muse, mutect2
- ZNF451 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 34/435 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100675001; called by muse, mutect2
- ABCA3 | c.449T>G p.V150G | Missense Mutation (SNP) | VAF 36/448 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ANXA4 | c.148C>A p.Q50K | Missense Mutation (SNP) | VAF 269/703 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- ATP2B4 | c.2056A>C p.K686Q | Missense Mutation (SNP) | VAF 82/426 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BUB1B | c.2765T>G p.L922R | Missense Mutation (SNP) | VAF 95/516 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- CDK5RAP3 | c.124A>G p.N42D | Missense Mutation (SNP) | VAF 96/380 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- CHD9 | c.1679A>C p.E560A | Missense Mutation (SNP) | VAF 231/614 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CNTNAP2 | c.629A>T p.D210V | Missense Mutation (SNP) | VAF 52/420 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CNTRL | c.3430T>C p.Y1144H | Missense Mutation (SNP) | VAF 102/293 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- COL10A1 | c.1189G>T p.D397Y | Missense Mutation (SNP) | VAF 46/730 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2
- COL4A5 | c.265A>G p.K89E | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- CYTH3 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 204/534 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- DAGLA | c.508A>C p.T170P | Missense Mutation (SNP) | VAF 253/577 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FAM71D | c.1008C>A p.N336K | Missense Mutation (SNP) | VAF 76/373 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- FAT3 | c.3668A>T p.E1223V | Missense Mutation (SNP) | VAF 117/527 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- FER1L6 | c.3565A>T p.K1189* | Nonsense Mutation (SNP) | VAF 95/294 reads (32%) | called by muse, mutect2, varscan2
- GALE | c.693C>A p.D231E | Missense Mutation (SNP) | VAF 44/502 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- GLDN | c.408C>A p.C136* | Nonsense Mutation (SNP) | VAF 60/506 reads (12%) | called by mutect2, varscan2
- GPATCH2L | c.1058del p.N353Ifs*102 | Frame Shift Del (DEL) | VAF 147/399 reads (37%) | called by mutect2, pindel, varscan2
- GREB1L | c.1644T>A p.Y548* | Nonsense Mutation (SNP) | VAF 30/724 reads (4%) | called by muse, mutect2
- HAUS7 | c.470G>C p.C157S | Missense Mutation (SNP) | VAF 209/408 reads (51%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HNRNPA3 | c.319C>G p.P107A | Missense Mutation (SNP) | VAF 163/497 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- HOOK3 | c.1514A>T p.E505V | Missense Mutation (SNP) | VAF 68/356 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- IGKV2D-26 | c.135del p.S46Vfs*27 | Frame Shift Del (DEL) | VAF 69/437 reads (16%) | called by mutect2, pindel, varscan2
- IPO9 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 132/334 reads (40%) | called by mutect2, varscan2
- IPO9 | c.1076A>T p.E359V | Missense Mutation (SNP) | VAF 140/359 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- LRIT1 | c.855G>C p.M285I | Missense Mutation (SNP) | VAF 96/366 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LTO1 | c.623A>C p.Q208P | Missense Mutation (SNP) | VAF 168/378 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); called by muse, varscan2
- MORF4L1 | c.282A>T p.E94D (on ENST00000331268 / NM_206839.2; = p.E55D on NM_006791.4) | Missense Mutation (SNP) | VAF 68/353 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RFPL1 | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 296/863 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- RNF43 | c.125_127del p.A42del | In Frame Del (DEL) | VAF 255/608 reads (42%) | called by pindel, varscan2
- SCARA3 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 133/385 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SDC4 | c.214_229del p.S72Kfs*9 | Frame Shift Del (DEL) | VAF 63/518 reads (12%) | called by mutect2, pindel, varscan2
- SETD2 | c.1302C>A p.Y434* | Nonsense Mutation (SNP) | VAF 160/258 reads (62%) | called by mutect2, varscan2
- SLC35F4 | c.954G>A p.M318I (on ENST00000339762 / NM_001352015.2; = p.M282I on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/368 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- SYT13 | c.391T>G p.F131V | Missense Mutation (SNP) | VAF 40/360 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- TASOR2 | c.1588G>T p.D530Y | Missense Mutation (SNP) | VAF 76/314 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TMEM39A | c.757A>C p.N253H | Missense Mutation (SNP) | VAF 185/326 reads (57%) | SIFT tolerated (0.53); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TTF1 | c.1094G>T p.S365I | Missense Mutation (SNP) | VAF 115/440 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBASH3B | c.1181G>T p.R394M | Missense Mutation (SNP) | VAF 197/421 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VHL | c.445_449delinsT p.A149Lfs*9 | Frame Shift Del (DEL) | VAF 91/189 reads (48%) | called by pindel, varscan2*
- VPS13D | c.12553C>A p.L4185I | Missense Mutation (SNP) | VAF 97/545 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- ZNF233 | c.1031G>A p.C344Y | Missense Mutation (SNP) | VAF 233/618 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- ANGPTL2 | c.1062T>A p.I354= | Silent (SNP) | VAF 131/465 reads (28%) | called by muse, mutect2, varscan2
- BEND5 | c.1065C>A p.V355= | Silent (SNP) | VAF 168/408 reads (41%) | called by muse, mutect2, varscan2
- BHLHE41 | c.366G>T p.S122= | Silent (SNP) | VAF 152/333 reads (46%) | called by mutect2, varscan2
- DCSTAMP | c.1266A>G p.A422= | Silent (SNP) | VAF 73/538 reads (14%) | called by muse, mutect2, varscan2
- DOK7 | c.1164C>T p.C388= | Silent (SNP) | VAF 416/954 reads (44%) | catalogued as rs763619811, COSV100403124; called by muse, mutect2
- EFHD2 | c.327C>T p.D109= | Silent (SNP) | VAF 60/349 reads (17%) | catalogued as rs12093459; called by muse, mutect2, varscan2
- FAM222B | c.219C>T p.H73= | Silent (SNP) | VAF 135/593 reads (23%) | catalogued as rs1179932267, COSV57935494; called by muse, mutect2, varscan2
- GPR39 | c.399C>T p.R133= | Silent (SNP) | VAF 36/854 reads (4%) | called by muse, mutect2
- HLA-DRA | c.423G>C p.V141= | Silent (SNP) | VAF 452/1198 reads (38%) | catalogued as COSV100895087; called by muse, mutect2
- LACTBL1 | c.414C>G p.L138= (on ENST00000618559; = p.L183= on NM_001289974.2) | Silent (SNP) | VAF 110/471 reads (23%) | called by muse, mutect2, varscan2
- LCP2 | c.507C>G p.S169= | Silent (SNP) | VAF 192/525 reads (37%) | called by muse, mutect2, varscan2
- OOSP2 | c.108C>T p.I36= | Silent (SNP) | VAF 80/449 reads (18%) | called by muse, mutect2, varscan2
- PSG1 | c.255C>T p.D85= | Silent (SNP) | VAF 206/577 reads (36%) | catalogued as rs1058959, COSV54944619, COSV54949080; called by muse, mutect2, varscan2
- SIX5 | c.2175G>C p.L725= | Silent (SNP) | VAF 126/743 reads (17%) | catalogued as rs1388624191; called by muse, mutect2, varscan2
- SRPK3 | c.432C>G p.V144= | Silent (SNP) | VAF 131/555 reads (24%) | called by muse, mutect2, varscan2
- SYNJ1 | c.3180A>G p.E1060= | Silent (SNP) | VAF 42/176 reads (24%) | called by muse, mutect2, varscan2
- TRPM5 | c.1857C>T p.D619= | Silent (SNP) | VAF 113/570 reads (20%) | catalogued as rs145136134; called by muse, mutect2, varscan2
- AK2 | c.94-2818G>C | Intron (SNP) | VAF 156/357 reads (44%) | called by muse, mutect2, varscan2
- GLI4 | c.223+440C>G | Intron (SNP) | VAF 114/503 reads (23%) | called by muse, mutect2, varscan2
- NADK | c.264-1893C>A | Intron (SNP) | VAF 161/735 reads (22%) | called by muse, mutect2, varscan2
- SATB1 | c.639+4077G>A | Intron (SNP) | VAF 17/125 reads (14%) | catalogued as rs1396713764; called by muse, mutect2, varscan2
- SPAG9 | c.590+837T>C | Intron (SNP) | VAF 184/399 reads (46%) | called by muse, mutect2, varscan2
